Somatic mutation profile of tumor specimen TCGA-XF-AAMR-01A (aliquot TCGA-XF-AAMR-01A-31D-A42E-08) from TCGA case TCGA-XF-AAMR, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 48.4 years (17,670 days).
Specimen TCGA-XF-AAMR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0020382-65d7-4d67-b980-31eb04d280f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAMR-10A (Blood Derived Normal), aliquot TCGA-XF-AAMR-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75539c46-e6ad-4742-9e82-f97141295c72

The open-access MAF lists 100 somatic variants for this specimen: 75 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 22, Splice Site 2, Nonsense Mutation 2, In Frame Del 2, 3'UTR 1, 5'UTR 1, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.3880C>T p.R1294C | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.735); catalogued as rs139771120; called by muse, mutect2, varscan2
- ABCC4 | c.98T>G p.I33S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV65312469; called by muse, mutect2, varscan2
- ACTG1 | c.1055T>C p.F352S | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59510406; called by muse, mutect2, varscan2
- ADSS2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV63695094, COSV63696391; called by muse, mutect2, varscan2
- AGAP4 | c.831G>C p.W277C | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101432611; called by muse, mutect2
- ARSF | c.638C>G p.S213C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs768556149, COSV63839563; called by muse, mutect2, varscan2
- ASIC5 | c.1469C>G p.P490R | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs543837967, COSV73332704; called by muse, mutect2, varscan2
- BBS12 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.079); catalogued as COSV58562029; called by muse, mutect2, varscan2
- BDP1 | c.5880G>C p.L1960F | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV62431274; called by muse, mutect2, varscan2
- BRCA1 | c.1670C>A p.T557K | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58789571; called by muse, varscan2
- BSX | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV58005545; called by muse, mutect2, varscan2
- C12orf50 | c.973A>G p.K325E | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as COSV53895158; called by muse, mutect2, varscan2
- CARS2 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as rs764879319, COSV57285878; called by muse, mutect2, varscan2
- CDC14B | c.1040G>A p.C347Y | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99685313; called by muse, mutect2
- CDC27 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50382907; called by muse, mutect2, varscan2
- CELSR2 | c.1030C>A p.P344T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs1365258645, COSV54771456; called by muse, mutect2, varscan2
- CELSR2 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.851); catalogued as COSV54771469; called by muse, mutect2, varscan2
- CNOT1 | c.5705G>A p.C1902Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV55316429; called by muse, mutect2, varscan2
- CNOT8 | c.297C>G p.F99L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV53585504; called by muse, mutect2, varscan2
- CUL2 | c.119C>A p.S40* | Nonsense Mutation (SNP) | VAF 21/108 reads (19%) | catalogued as COSV101039039; called by muse, mutect2, varscan2
- CYB561D1 | c.509G>C p.G170A | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60204784; called by muse, mutect2, varscan2
- ELAVL3 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV63645178; called by muse, mutect2
- FAM117B | c.847-1G>C p.X283_splice | Splice Site (SNP) | VAF 12/77 reads (16%) | catalogued as COSV57418914; called by muse, mutect2, varscan2
- FAM161B | c.730G>A p.E244K (on ENST00000651776; = p.E181K on NM_152445.3) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371012373; called by mutect2, varscan2
- FAM193A | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100219299, COSV61193813; called by muse, mutect2, varscan2
- FAM214A | c.3075G>A p.L1025= | Splice Region (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99957684; called by muse, mutect2, varscan2
- FAR2 | c.1182C>A p.F394L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1298843090, COSV51725592; called by muse, mutect2, varscan2
- FPGT | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV63839556, COSV63844365; called by muse, mutect2, varscan2
- GRK4 | c.1543G>A p.E515K (on ENST00000398052 / NM_182982.3; = p.E483K on NM_005307.3) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV61668096; called by muse, varscan2
- HOXA9 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.041); catalogued as COSV58656090; called by muse, mutect2, varscan2
- ICE1 | c.5902G>C p.E1968Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs758714078, COSV56824358; called by muse, mutect2, varscan2
- KAT8 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV54896532; called by muse, mutect2, varscan2
- KIF26B | c.4192G>T p.A1398S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as rs1449023546, COSV63641154; called by muse, mutect2, varscan2
- KIF5B | c.1762A>G p.T588A | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.467); catalogued as COSV56652670; called by muse, mutect2, varscan2
- LHX9 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as COSV100435640; called by muse, mutect2
- LILRA5 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV56642674; called by muse, mutect2, varscan2
- MAP7 | c.638-1G>A p.X213_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | catalogued as COSV63419420; called by muse, mutect2, varscan2
- MICAL2 | c.3163C>T p.H1055Y | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV56320165; called by muse, mutect2, varscan2
- MUC17 | c.10912A>T p.T3638S | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as rs1219002240, COSV60288000; called by muse, mutect2, varscan2
- NALCN | c.4621T>G p.S1541A | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV51934294; called by muse, mutect2, varscan2
- NCOA6 | c.2158C>G p.Q720E | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as COSV62863465; called by muse, mutect2, varscan2
- NSF | c.2056T>G p.F686V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV56574797; called by muse, mutect2, varscan2
- NUMA1 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV61185434; called by muse, mutect2, varscan2
- OR8B8 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.948); catalogued as COSV60144281, COSV60144493; called by muse, mutect2, varscan2
- PACSIN1 | c.643G>C p.D215H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99762886; called by muse, mutect2
- PDS5A | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.287); catalogued as rs1289511658, COSV57825677; called by muse, mutect2, varscan2
- PELI2 | c.757C>G p.L253V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV50711127; called by muse, mutect2, varscan2
- PLEKHA7 | c.3302C>T p.T1101M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as rs141880623; called by muse, mutect2, varscan2
- PPP1R16A | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746197210, COSV52953042; called by muse, mutect2, varscan2
- PPWD1 | c.1271C>G p.S424C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV54333635; called by muse, mutect2, varscan2
- PTPRB | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV54240149; called by muse, mutect2, varscan2
- RAPGEF3 | c.1340C>T p.A447V (on ENST00000389212; = p.A405V on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.116); catalogued as rs201879522, COSV50205647; called by muse, mutect2, varscan2
- ROBO2 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59910477; called by muse, mutect2, varscan2
- RYR1 | c.2434G>C p.E812Q | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV62096751; called by muse, mutect2, varscan2
- SNX18 | c.778G>C p.V260L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV57987776, COSV57989161; called by muse, mutect2, varscan2
- ST8SIA5 | c.60C>A p.F20L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | PolyPhen benign (0.13); catalogued as COSV59331795; called by muse, mutect2, varscan2
- SYNJ1 | c.2406G>C p.Q802H | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59148086; called by muse, mutect2, varscan2
- TBC1D9 | c.875G>A p.S292N | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.99); PolyPhen benign (0.015); catalogued as rs370816280; called by muse, mutect2, varscan2
- TCFL5 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.985); catalogued as COSV53896820; called by muse, mutect2, varscan2
- TECTA | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.637); catalogued as COSV50706445; called by muse, mutect2, varscan2
- TGFB1I1 | c.744C>A p.H248Q (on ENST00000394863 / NM_001042454.3; = p.H231Q on NM_015927.4) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1567383477, COSV62357913; called by muse, mutect2
- TLR3 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as COSV57168523, COSV99710842; called by muse, mutect2, varscan2
- TMEM62 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53041030; called by muse, mutect2, varscan2
- TMEM87A | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67746856; called by muse, mutect2, varscan2
- TRMT10B | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.056); catalogued as COSV53050346; called by muse, mutect2, varscan2
- TTLL7 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV53084180; called by muse, mutect2, varscan2
- UBA52 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV55889008; called by muse, mutect2, varscan2
- UHRF2 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV52792610; called by muse, mutect2, varscan2
- VWA3A | c.3094G>C p.A1032P | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.395); catalogued as COSV55390706; called by muse, mutect2, varscan2
- YY2 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.799); catalogued as rs767326908, COSV63411461; called by muse, mutect2, varscan2
- PRAMEF20 | c.1421G>A p.C474Y | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PRAMEF20 | c.1422C>G p.C474W | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- PTAR1 | c.847_849del p.E283del | In Frame Del (DEL) | VAF 10/54 reads (19%) | called by pindel, varscan2
- TSC1 | c.546_557del p.S183_A186del | In Frame Del (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- ZFP36L1 | c.482dup p.H162Pfs*19 | Frame Shift Ins (INS) | VAF 16/87 reads (18%) | called by mutect2, pindel, varscan2
- C8orf34 | c.381C>T p.L127= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV61379111; called by muse, mutect2, varscan2
- CACNA1H | c.7017C>G p.P2339= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99326406; called by muse, mutect2
- CASS4 | c.765C>G p.V255= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV64386393; called by muse, mutect2, varscan2
- CDAN1 | c.1998C>T p.L666= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV62331956; called by muse, mutect2, varscan2
- CYP7A1 | c.708G>A p.E236= | Silent (SNP) | VAF 28/131 reads (21%) | catalogued as COSV56963428, COSV56965989; called by muse, mutect2, varscan2
- FOXM1 | c.1635G>A p.R545= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV61205950; called by mutect2, varscan2
- HTT | c.8406C>G p.L2802= | Silent (SNP) | VAF 33/165 reads (20%) | catalogued as COSV61861754; called by muse, mutect2, varscan2
- IGHMBP2 | c.2865G>A p.G955= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV99661867; called by muse, mutect2
- JAKMIP1 | c.1359G>A p.T453= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as rs769869746, COSV51527872; called by muse, mutect2, varscan2
- NAIP | c.519C>G p.V173= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV52001309; called by muse, mutect2, varscan2
- OTUD7A | c.468G>A p.L156= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs779660581, COSV61038608; called by muse, mutect2, varscan2
- PTPRB | c.687G>A p.V229= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV54240164; called by muse, mutect2, varscan2
- RGS4 | c.279C>T p.I93= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV63357410; called by muse, mutect2, varscan2
- SDC2 | c.603G>A p.A201= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs770229518, COSV56227441; called by muse, mutect2
- SLC12A5 | c.2292C>T p.F764= (on ENST00000454036 / NM_001134771.2; = p.F741= on NM_020708.5) | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV54793283; called by muse, mutect2, varscan2
- SLC9A7 | c.1401C>T p.L467= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV60380007; called by muse, mutect2, varscan2
- TBC1D16 | c.813C>T p.F271= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs1352391649, COSV60477563; called by muse, mutect2, varscan2
- TBL2 | c.231C>T p.F77= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as rs782173531, COSV59787050; called by muse, mutect2, varscan2
- TLN2 | c.7485G>A p.V2495= | Silent (SNP) | VAF 31/194 reads (16%) | catalogued as rs200809264, COSV60889591; called by muse, mutect2, varscan2
- TUBG1 | c.1355G>A p.*452= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV52220364; called by muse, varscan2
- UHRF1BP1 | c.3117C>T p.L1039= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs553741837, COSV51955337; called by muse, mutect2, varscan2
- ZBTB40 | c.612G>A p.A204= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs146825007; called by muse, mutect2, varscan2
- FAM172A | c.*1G>A | 3'UTR (SNP) | VAF 5/15 reads (33%) | catalogued as COSV101232671; called by muse, mutect2, varscan2
- IKBIP | c.297+8228T>C | Intron (SNP) | VAF 8/59 reads (14%) | catalogued as COSV54489597; called by muse, mutect2, varscan2
- PUM3 | c.-1G>A | 5'UTR (SNP) | VAF 14/55 reads (25%) | catalogued as rs559671705, COSV101193142; called by muse, mutect2, varscan2
